TCGA case TCGA-AF-6672 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6221496d-40cc-4071-969f-6fbcba4f573c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 43 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 43.7 years (15,965 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 748 days (2.0 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 18; Lymph nodes tested: 37; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 199 days; Number of cycles: 12; Treatment dose: 51,786 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 197 days; Number of cycles: 12; Treatment dose: 8,639 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 197 days; Number of cycles: 12; Treatment dose: 1,400 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 183 days; Number of cycles: 11; Treatment dose: 1,578 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 146 days; Days to treatment end: 185 days; Treatment dose: 5,040 cGy; Course number: 1; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 44.5 years (16,244 days); Days to diagnosis: 279 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 304 days; Treatment anatomic sites: Liver.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 45.0 years (16,426 days); Days to diagnosis: 461 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (5 entries)
- Days to follow up: 224 days; Disease response: Tumor Free.
- Day 279 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 279 days.
- Day 461 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 748 days (2.0 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 316.

Molecular and laboratory tests
- CEA: 9.6 ng/mL.
- KRAS mutation, nos: Positive; Mutation codon: 12.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 93.8 kg; Height: 172.7 cm; BMI: 31.4.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AF-6672-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.8.
  Slide TCGA-AF-6672-01A-01-BS1: Section location: Bottom; Percent tumor cells: 77; Percent tumor nuclei: 80; Percent normal cells: 8; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-AF-6672-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-AF-6672-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AF-6672-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Rectum; Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 9.6; Lymphovascular invasion indicator: Yes; Microsatellite instability: No; Loci tested count: 5; KRAS gene analysis indicator: Yes; KRAS mutation found: Yes; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 748 days; disease-specific survival: no event (censored), 748 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 279 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AF-6672-01A-11D-1825-01): tumor purity 0.71, ploidy 3.14, whole-genome doublings 1.
